Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A5W8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A5W8-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site: Kidney NOS
C64.9
JW 6/18/13

Diagnosis:

A: Kidney, right, partial nephrectomy

Procedure: Partial nephrectomy

Laterality: Right

Histologic tumor type/subtype: Renal cell carcinoma, papillary type

Sarcomatoid features: Not identified

Histologic grade (if applicable): Furman grade 3 (of 4)

Tumor size (greatest dimension): 11.8 cm (gross measurement)

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not submitted

Gerota's fascia: Not submitted

Renal sinus: Not submitted

Major veins (renal vein or segmental branches, IVC): Not submitted

Ureter: Not submitted

Venous (large vessel): Not submitted

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Negative, 2mm (A1)

Renal capsular margin (partial nephrectomy only): Negative, < 1 mm (A5)

Adrenal gland: Not submitted

Lymph nodes: Not submitted

Pathologic findings in non-neoplastic kidney: Scattered sclerotic glomeruli and arterioles with intimal thickening are present in sections taken from grossly uninvolved kidney parenchyma adjacent to tumor.

[page 2 of 3]
AJCC Staging:

pT2b

pNX

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old man with a right renal mass. Per , the patient has a 9 cm right renal mass suggestive of possible renal cell carcinoma and most likely brain metastasis.

Gross Description:

Specimen fixation: formalin

Type of specimen: partial nephrectomy

Side of specimen: right

Size and weight of specimen: 745.0 grams, 12.0 x 9.2 x 9.5 cm

Orientation: The parenchymal margin is inked black, and the capsule is inked blue.

Presence/absence of adrenal gland: absent

Tumor site: per , posterior central right kidney

Tumor description: yellow/brown, multinodular and well circumscribed with extensive areas of hemorrhage and necrosis

Tumor size: 11.8 x 9.2 x 9.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: grossly confined

Extent of invasion:

Perirenal adipose tissue: not submitted

Gerota' s fascia: not submitted

[page 3 of 3]
Renal vein: not submitted

Ureter: not submitted

Renal Sinus: not submitted

Pelvic/Caliceal: limited uninvolved kidney for evaluation

Adrenal: not submitted

Parenchymal margin: 2 mm

Capsule: 1 mm

Description of kidney away from tumor: extremely limited, uninvolved kidney available for evaluation (4.7 x 7.5 x 0.1-2.1 cm); appears tan and firm without grossly evident lesions; no urothelium is available for evaluation

Hilar lymph nodes: not submitted

Other significant findings: none

Tissue submitted for special investigations: Tumor is submitted to Tissue Procurement

Digital picture: not taken

Block summary:

(Inking: parenchymal margin=black, capsule=blue)

A1-A3 - tumor in relation to black inked parenchymal margin

A4 - tumor in relation to grossly uninvolved kidney

A5-A6 - tumor in relation to blue inked capsule

A7-A12 - additional representative sections of tumor

A13 - representative section of grossly uninvolved kidney (nearest tumor 3 mm away)

Tissue remains.

MPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 4c536832-0f97-4944-9a0c-13b21153237c (TCGA-B9-A5W8.4B22FF88-FDD8-4B37-A300-DCB4B41A6273.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).